Somatic mutation profile of tumor specimen TCGA-DD-A1EJ-01A (aliquot TCGA-DD-A1EJ-01A-11D-A152-10) from TCGA case TCGA-DD-A1EJ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 71.2 years (26,009 days).
Specimen TCGA-DD-A1EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7704eb9-9582-4b1a-8e12-cdc15a2ad629.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EJ-10A (Blood Derived Normal), aliquot TCGA-DD-A1EJ-10A-01D-A152-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1882ea06-160e-4a6e-9cba-22b6a652ed48

The open-access MAF lists 66 somatic variants for this specimen: 50 protein-altering or splice-affecting, 10 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 10, 3'UTR 4, Frame Shift Del 3, Intron 2, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1004A>T p.K335I | Missense Mutation (SNP) | VAF 83/165 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62688046, COSV62689047, COSV62695316; called by muse, mutect2, varscan2
- RXRA | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 22/73 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519958, COSV62683447, COSV62683496, COSV62683653; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7727T>A p.L2576* | Nonsense Mutation (SNP) | VAF 17/168 reads (10%) | catalogued as rs544493291, COSV71283511; called by muse, mutect2
- APOH | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 71/104 reads (68%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.666); catalogued as rs55645281, COSV52771453; called by muse, mutect2, varscan2
- ATP13A5 | c.869C>T p.P290L | Missense Mutation (SNP) | VAF 90/196 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV60865914; called by muse, mutect2, varscan2
- CACNA1D | c.1218C>T p.S406= | Splice Region (SNP) | VAF 462/925 reads (50%) | catalogued as rs1425686360, COSV55437919; called by muse, mutect2, varscan2
- CD5 | c.*2+2T>A | Splice Site (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100075357; called by muse, mutect2, varscan2
- CFAP298 | c.697A>G p.I233V | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs370327238; called by muse, mutect2, varscan2
- CGREF1 | c.89C>A p.S30Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV53148446; called by muse, mutect2
- CLCN1 | c.1804A>G p.T602A | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV58367499; called by muse, mutect2, varscan2
- CPB1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs761204342, COSV51571374, COSV51577956; called by muse, mutect2, varscan2
- CSMD3 | c.7149dup p.V2384Cfs*22 (on ENST00000297405 / NM_001363185.1; = p.V2280Cfs*22 on NM_052900.3) | Frame Shift Ins (INS) | VAF 40/125 reads (32%) | catalogued as rs1230860045; called by mutect2, pindel, varscan2
- DISC1 | c.593C>A p.T198N | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.211); catalogued as COSV54400564, COSV99698347; called by muse, mutect2, varscan2
- DNAJA2 | c.1160G>T p.R387M | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV57694385, COSV57695216; called by muse, mutect2, varscan2
- GAREM1 | c.971A>G p.H324R | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1238835671, COSV52505992; called by muse, mutect2, varscan2
- GDPD4 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as COSV60017190; called by muse, mutect2, varscan2
- GNB5 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as COSV55897852; called by muse, mutect2, varscan2
- GRIN3B | c.1076G>A p.S359N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs778317218, COSV52258664; called by muse, mutect2, varscan2
- HELZ | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV62376420; called by muse, mutect2, varscan2
- HTR7 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs780476203, COSV53282993; called by muse, mutect2, varscan2
- INTS4 | c.617A>T p.D206V | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV71087178; called by muse, mutect2, varscan2
- KALRN | c.3460C>G p.L1154V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53753364; called by muse, varscan2
- KCNH1 | c.1118A>G p.E373G (on ENST00000271751 / NM_172362.3; = p.E346G on NM_002238.4) | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV55070148; called by muse, mutect2, varscan2
- KLF9 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as COSV65807323; called by muse, mutect2, varscan2
- LAMA2 | c.3862G>A p.V1288I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs758134778, COSV70338998; ClinVar: uncertain significance; called by muse, mutect2
- LARGE1 | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61657936; called by muse, mutect2, varscan2
- LILRB5 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.937); catalogued as rs1173357717, COSV60254627; called by muse, mutect2, varscan2
- MLXIPL | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57666844; called by muse, mutect2, varscan2
- OR51I2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs754539560, COSV58297944; called by muse, mutect2, varscan2
- PDE4B | c.505T>G p.F169V | Missense Mutation (SNP) | VAF 151/235 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV58466814; called by muse, mutect2, varscan2
- PPP2R2C | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs1401064445, COSV100160251, COSV59441969; called by muse, mutect2, varscan2
- PTPRZ1 | c.6050C>T p.P2017L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV66430565; called by muse, mutect2, varscan2
- RAB7A | c.76A>G p.N26D | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV54039755; called by muse, mutect2, varscan2
- SEMA3E | c.1648A>G p.T550A | Missense Mutation (SNP) | VAF 71/141 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57080174; called by muse, mutect2, varscan2
- SEMA6D | c.2529C>A p.N843K (on ENST00000316364 / NM_153618.2; = p.N781K on NM_020858.2) | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.138); catalogued as COSV60372979; called by muse, mutect2, varscan2
- SIX2 | c.676T>A p.S226T | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.827); catalogued as COSV57390068; called by muse, mutect2
- SMCO3 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 67/88 reads (76%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53761766; called by muse, mutect2, varscan2
- TMEM132E | c.912C>A p.D304E (on ENST00000321639; = p.D394E on NM_001304438.2) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV58694739; called by muse, mutect2, varscan2
- TTN | c.30388G>C p.V10130L (on ENST00000591111; = p.V9203L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 116/312 reads (37%) | PolyPhen benign (0.167); catalogued as COSV59895601; called by muse, mutect2, varscan2
- WASF2 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1246146048, COSV71004813; called by muse, mutect2, varscan2
- ZNF326 | c.1400A>C p.K467T | Missense Mutation (SNP) | VAF 71/370 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61034363; called by muse, mutect2, varscan2
- CNTN1 | c.824G>A p.W275* | Nonsense Mutation (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- FBXL7 | c.1238del p.P413Lfs*13 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- GJB1 | c.89_94dup p.I30_F31dup | In Frame Ins (INS) | VAF 64/98 reads (65%) | called by mutect2, varscan2
- HMCN2 | c.5615C>G p.T1872S | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- OSBPL11 | c.40_44del p.E14Rfs*25 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | called by mutect2, pindel, varscan2
- PRRC2A | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RXRB | c.527del p.P176Lfs*4 | Frame Shift Del (DEL) | VAF 29/61 reads (48%) | called by mutect2, pindel, varscan2
- SMIM7 | c.5T>A p.I2N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- SOCS6 | c.684_704del p.D228_L234del | In Frame Del (DEL) | VAF 56/120 reads (47%) | called by mutect2, pindel*, varscan2
- DAPK1 | c.2964G>A p.L988= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV63784341; called by muse, mutect2, varscan2
- DENND6A | c.672C>T p.H224= | Silent (SNP) | VAF 152/355 reads (43%) | catalogued as COSV60767566; called by muse, mutect2, varscan2
- EPG5 | c.7545C>G p.P2515= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV56344758; called by muse, mutect2, varscan2
- MUC2 | c.378G>A p.L126= | Silent (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- NAV2 | c.1899C>G p.S633= (on ENST00000396087 / NM_001244963.2; = p.S610= on NM_145117.5) | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV62315649; called by muse, mutect2, varscan2
- NLGN4X | c.2043C>T p.V681= | Silent (SNP) | VAF 91/241 reads (38%) | catalogued as rs770117821, COSV52005134, COSV52039876; called by muse, mutect2, varscan2
- SGCE | c.834A>T p.P278= (on ENST00000647096; = p.P242= on NM_003919.3) | Silent (SNP) | VAF 101/275 reads (37%) | catalogued as COSV56015642; called by muse, mutect2, varscan2
- SLITRK1 | c.1456C>T p.L486= | Silent (SNP) | VAF 24/108 reads (22%) | catalogued as COSV65674317; called by mutect2, varscan2
- STON1 | c.1623G>A p.V541= | Silent (SNP) | VAF 41/273 reads (15%) | catalogued as COSV59126328; called by muse, mutect2, varscan2
- UGGT2 | c.1674A>G p.V558= | Silent (SNP) | VAF 100/248 reads (40%) | catalogued as COSV65072408; called by muse, mutect2, varscan2
- ARL4D | c.*83A>C | 3'UTR (SNP) | VAF 22/86 reads (26%) | catalogued as COSV100186465; called by muse, mutect2
- CARD19 | c.*847T>G | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- KLHDC7B | c.*614G>C | 3'UTR (SNP) | VAF 37/62 reads (60%) | catalogued as COSV101192998; called by muse, mutect2, varscan2
- RABGAP1L | c.1711-89393G>T | Intron (SNP) | VAF 66/311 reads (21%) | called by muse, mutect2, varscan2
- SRSF8 | c.*2997A>G | 3'UTR (SNP) | VAF 277/526 reads (53%) | catalogued as rs1429381821; called by muse, mutect2, varscan2
- TRIM55 | c.1524+1372A>C | Intron (SNP) | VAF 111/236 reads (47%) | catalogued as COSV52543824; called by muse, varscan2
